Gene-level copy-number profile of tumor specimen TCGA-3B-A9HV-01A from TCGA case TCGA-3B-A9HV, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 48.3 years (17,638 days).
Specimen TCGA-3B-A9HV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.6861a568-0744-4802-900b-6b81e3de8a66.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3B-A9HV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0b82dc64-4f60-4bb0-9f2b-817d5eda563f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 1,470; copy number 2: 5,493; copy number 3: 8,276; copy number 4: 40,064; copy number 5: 1,700; copy number 6: 737; copy number 7: 1,936; copy number 8: 95; copy number 9: 1; copy number 10: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3B-A9HV-01A-11D-A38Y-01): tumor purity 0.99, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:2,033,508–2,165,552, 3 genes (within-gene range 0–1): AC245164.1, MYOM2, MIR7160.
- chr9:81,583,683–81,776,900, 3 genes (within-gene range 0–1): TLE1, AL591368.1, RNU6-1035P.
- chr13:48,232,612–48,599,436, 9 genes (within-gene range 0–1): ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2.
- chr14:67,819,779–68,869,951, 17 genes (within-gene range 0–3): RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P, ZFP36L1, MAGOH3P, BLZF2P.
- chr14:68,887,785–68,888,084, 1 gene: HMGN1P3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:77,216,416–77,216,878, 1 gene, copy number 9: AC008638.3.
- chr12:114,077,133–114,113,489, 4 genes, copy number 10: AC010183.1, AC010183.2, HAUS8P1, GLULP5.

Autosomal genes at a single copy (total copy number 1): 1,470. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
